Surgical pathology report (de-identified scan), TCGA case TCGA-BR-A4CR, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-A4CR-01A (Primary Tumor).

Gross Description:

Microscopic Description:

Diagnosis Details:

Comments:

Formatted Path Reports: STOMACH TISSUE CHECKLIST

Specimen type: Excision of tumor

Tumor site: Fundus

Tumor size: 12 x 10 x 1 cm

Tumor features: None specified

Histologic type: Adenocarcinoma

Histologic grade: Poorly differentiated

Tumor extent: Adjacent structures (specify) - Esophagus, omentum

Lymph nodes: 8/8 positive for metastasis (Intraabdominal 8/8)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Perineural invasion: Not specified

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

ICD-0-3

Adenocarcinoma, NOS 8140/3

Site: stomach, fundus C16.1

lw
9/27/12

ICV Number (circle)	813112	

lw
9/27/12

Source: NCI Genomic Data Commons file 7e926bba-e2d3-4c84-b474-a3c61a2154e4 (TCGA-BR-A4CR.71D66FC2-7513-4A62-AB65-762A30046473.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).